Gene-level copy-number profile of tumor specimen TARGET-10-PASSZA-09A from TARGET case TARGET-10-PASSZA, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 14.8 years (5,416 days).
Specimen TARGET-10-PASSZA-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-ALL-P2.5b3621ad-9454-599f-9c48-ad2892b10416.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-10-PASSZA-14A (bone marrow normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 359 have no estimate.
https://portal.gdc.cancer.gov/files/d10bffaf-785a-463a-a061-1ca501120fa4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 111; copy number 1: 2,463; copy number 2: 57,666; copy number 3: 18; copy number 4: 6.

Homozygous deletions (total copy number 0; autosomes only): 111 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,273,587–38,311,808, 6 genes: TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1.
- chr14:21,841,240–22,528,586, 105 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 76. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
